Somatic mutation profile of tumor specimen TCGA-FS-A4FD-06A (aliquot TCGA-FS-A4FD-06A-11D-A25O-08) from TCGA case TCGA-FS-A4FD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.8 years (16,726 days).
Specimen TCGA-FS-A4FD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c113dbd-149a-4654-88ee-d3aa3191c349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4FD-10B (Blood Derived Normal), aliquot TCGA-FS-A4FD-10B-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39ac4e92-ee39-41d1-8457-e107c6546ad6

The open-access MAF lists 532 somatic variants for this specimen: 359 protein-altering or splice-affecting, 164 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 337, Silent 164, Nonsense Mutation 15, Intron 6, Splice Region 3, Frame Shift Ins 2, RNA 2, In Frame Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LCE1F | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 42/84 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV57669605; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 36/76 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AADACL4 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV66106684; called by muse, mutect2, varscan2
- ABCA10 | c.4115C>T p.P1372L | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV52225656; called by muse, mutect2, varscan2
- ABCA12 | c.4696G>A p.E1566K (on ENST00000272895 / NM_173076.3; = p.E1248K on NM_015657.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs537765994, COSV55955863; called by muse, mutect2, varscan2
- ABRA | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 135/201 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.425); catalogued as rs368270742, COSV61732483; called by muse, mutect2, varscan2
- AC013489.1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.454); catalogued as COSV51552343, COSV99076157; called by muse, mutect2, varscan2
- ACRBP | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV57524571; called by muse, mutect2, varscan2
- ACTA2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.442); catalogued as COSV56517151; called by muse, mutect2, varscan2
- ACTC1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs543030688, CM0910610, COSV51758568; called by muse, mutect2, varscan2
- ACYP1 | c.44T>G p.F15C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV53135365; called by muse, mutect2, varscan2
- ADA2 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV52832209; called by muse, mutect2
- ADAM19 | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs35242691, COSV57433616, COSV57435619; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1404C>T p.T468= | Splice Region (SNP) | VAF 8/11 reads (73%) | catalogued as COSV56476131; called by muse, mutect2, varscan2
- ADAMTS12 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV61268414; called by muse, mutect2, varscan2
- ADAMTS18 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs768100645, COSV51398426; called by muse, mutect2, varscan2
- ADCY1 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.716); catalogued as COSV52037691; called by muse, mutect2
- ADCY10 | c.4622C>T p.S1541F | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV63242355; called by muse, mutect2, varscan2
- ADCY8 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53901251, COSV53906580, COSV99650702; called by muse, mutect2, varscan2
- AKAP12 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs145059917, COSV53577820; called by muse, mutect2, varscan2
- ALDH6A1 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63246745; called by muse, mutect2, varscan2
- AMZ1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56687918; called by muse, mutect2, varscan2
- ANK3 | c.5327C>T p.S1776F | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs138929485, COSV55067086; called by muse, mutect2, varscan2
- ANKAR | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV55615019; called by muse, mutect2, varscan2
- ANKRD30A | c.2905C>T p.H969Y (on ENST00000611781; = p.H913Y on NM_052997.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV64614497; called by muse, mutect2
- ANXA9 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV64485175; called by muse, mutect2, varscan2
- APOB | c.8251G>A p.E2751K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs201985284, COSV51942366; called by muse, mutect2
- APOB | c.4941T>G p.I1647M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51942381; called by muse, mutect2, varscan2
- ARHGAP28 | c.722C>T p.S241F (on ENST00000383472 / NM_001366230.1; = p.S82F on NM_001010000.3) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV51641153; called by muse, mutect2, varscan2
- ASXL3 | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs866757981, COSV52471458; called by muse, mutect2, varscan2
- ATP10B | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as rs867675854, COSV58779585; called by muse, mutect2, varscan2
- ATP8A1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV52532212, COSV52539809; called by muse, mutect2, varscan2
- ATP8B4 | c.2897C>T p.S966L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372149438; called by muse, mutect2, varscan2
- ATP8B4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752810289, COSV52718864; called by muse, mutect2, varscan2
- B3GAT2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV57772347; called by mutect2, varscan2
- BAHCC1 | c.6881C>T p.P2294L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs1215229479, COSV57029098; called by muse, mutect2, varscan2
- BRPF3 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV60208319; called by muse, varscan2
- C6orf89 | c.1022G>A p.G341E (on ENST00000373685; = p.G348E on NM_152734.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62102373; called by muse, mutect2, varscan2
- CACNG3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50072151, COSV50073264; called by muse, mutect2, varscan2
- CALCOCO2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV51952680; called by muse, mutect2, varscan2
- CALML3 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1307280920, COSV59449565; called by muse, mutect2, varscan2
- CAMK2G | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59480504; called by muse, mutect2, varscan2
- CAPN11 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67238307, COSV67239933; called by muse, mutect2, varscan2
- CAPRIN1 | c.818C>G p.P273R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.063); catalogued as COSV100403898, COSV58220899; called by muse, mutect2, varscan2
- CCDC62 | c.140T>A p.M47K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53435265, COSV99457162; called by muse, mutect2, varscan2
- CCDC73 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV58800969; called by muse, mutect2
- CCDC74A | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.301); catalogued as rs145934024, COSV54605168; called by muse, mutect2, varscan2
- CCT8L2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV63463030; called by muse, mutect2, varscan2
- CDH7 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV59888974; called by muse, mutect2, varscan2
- CDK13 | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51702733; called by muse, mutect2, varscan2
- CDS1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV55688935; called by muse, mutect2, varscan2
- CEACAM8 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV54991112; called by muse, mutect2, varscan2
- CFAP43 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV53379240; called by muse, mutect2, varscan2
- CFAP91 | c.2161A>G p.K721E | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56342346; called by muse, mutect2, varscan2
- CHRM3 | c.1387C>A p.L463M | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.101); catalogued as COSV55088977, COSV55094278; called by muse, mutect2, varscan2
- CHRNA5 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55139285; called by muse, mutect2
- CHRNA6 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs766345085, COSV52379593; called by muse, mutect2, varscan2
- CKAP5 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV56370274; called by muse, mutect2, varscan2
- CLK2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs146292560, COSV62876402, COSV62877910; called by muse, mutect2, varscan2
- CNGA3 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV55625630; called by muse, mutect2, varscan2
- CNN1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52956419; called by muse, mutect2, varscan2
- CNTN4 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV61875871; called by muse, mutect2, varscan2
- CNTNAP2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs867001883, COSV100665155, COSV62143236; called by muse, mutect2, varscan2
- COL4A1 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65428065; called by muse, mutect2
- COL5A1 | c.4875G>A p.M1625I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs267602163, COSV65671417; called by muse, mutect2, varscan2
- COL5A2 | c.4229G>A p.G1410E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV66411373; called by muse, mutect2, varscan2
- COL5A2 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66411378; called by muse, mutect2, varscan2
- COL7A1 | c.3869G>A p.G1290E | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV60397977; called by muse, mutect2, varscan2
- CPAMD8 | c.1559C>T p.S520F (on ENST00000651564; = p.S473F on NM_015692.5) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV52232834, COSV52233401; called by muse, mutect2, varscan2
- CR1 | c.3661G>A p.E1221K | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV65459919; called by muse, mutect2, varscan2
- CRB2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63504185; called by muse, mutect2, varscan2
- CRTAM | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57069279; called by muse, mutect2, varscan2
- CSMD3 | c.2540G>A p.G847E (on ENST00000297405 / NM_001363185.1; = p.G743E on NM_052900.3) | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52233261; called by muse, mutect2, varscan2
- CTAGE1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV66943914; called by muse, mutect2, varscan2
- CTSE | c.863G>A p.G288E (on ENST00000360218; = p.G283E on NM_001910.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158622624, COSV63061178; called by muse, mutect2, varscan2
- CYP2C18 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53673347; called by muse, mutect2, varscan2
- CYP4F12 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV61171875; called by muse, mutect2, varscan2
- CYTIP | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs866095217, COSV51634551, COSV51634992; called by muse, mutect2, varscan2
- DACH1 | c.1816C>T p.P606S (on ENST00000619232 / NM_001366712.1; = p.P352S on NM_004392.6) | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.325); catalogued as COSV57492586; called by muse, mutect2, varscan2
- DDX43 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64837359; called by muse, mutect2, varscan2
- DEGS2 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.987); catalogued as COSV59784775; called by muse, mutect2, varscan2
- DGKI | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as rs750429253, COSV55959948; called by muse, mutect2, varscan2
- DNAH3 | c.11034C>A p.H3678Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779171405, COSV54533078; called by muse, mutect2, varscan2
- DNAH6 | c.1960C>T p.H654Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.424); catalogued as rs1244574349, COSV52869660; called by muse, mutect2, varscan2
- DNAH8 | c.12556G>A p.D4186N | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59461229; called by muse, mutect2, varscan2
- DPH2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as rs1256907031, COSV52544061; called by muse, mutect2, varscan2
- DSEL | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59492721; called by muse, mutect2, varscan2
- DSG3 | c.1251C>A p.N417K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV57127657; called by muse, mutect2, varscan2
- DSG4 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57393968; called by muse, mutect2, varscan2
- DST | c.2450C>G p.A817G (on ENST00000361203 / NM_001374722.1; = p.A491G on NM_001723.6) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV55024677; called by muse, mutect2
- DUOX2 | c.2678A>G p.N893S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV66533021; called by muse, mutect2, varscan2
- DYNC2H1 | c.1808T>C p.V603A | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV62099066; called by muse, mutect2
- EFCAB5 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.169); catalogued as rs1567749698, COSV57932742; called by muse, mutect2, varscan2
- EPG5 | c.4660C>T p.R1554W | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs749496135, COSV56352139; called by muse, mutect2, varscan2
- EXPH5 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as COSV56204679; called by muse, mutect2, varscan2
- EXPH5 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as COSV56204690; called by muse, mutect2, varscan2
- F13B | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs748341394, COSV66373444; called by muse, mutect2, varscan2
- FAM47A | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV60498102; called by muse, mutect2, varscan2
- FAM83B | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100174333; called by muse, mutect2, varscan2
- FGF12 | c.430G>A p.E144K (on ENST00000454309 / NM_021032.5; = p.E82K on NM_004113.6) | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53174758; called by muse, mutect2, varscan2
- FGF21 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV55810762; called by muse, mutect2
- FGF5 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs137903755; called by muse, mutect2, varscan2
- FIBCD1 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV53394337, COSV99447113; called by muse, mutect2, varscan2
- FLT1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as rs1244106213, COSV56733174; called by muse, mutect2, varscan2
- FLT1 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.95); catalogued as COSV56733186; called by muse, mutect2, varscan2
- FNDC3A | c.2051-1G>A p.X684_splice (on ENST00000492622 / NM_001079673.2; = p.X628_splice on NM_014923.5) | Splice Site (SNP) | VAF 34/59 reads (58%) | catalogued as COSV68133938; called by muse, mutect2, varscan2
- FOLH1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57051921, COSV99923753; called by muse, mutect2, varscan2
- FOXD4L4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as rs1204119954; called by muse, mutect2, varscan2
- FREM1 | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV66526162; called by muse, mutect2, varscan2
- FRMD6 | c.1610C>T p.S537F (on ENST00000344768 / NM_001267046.2; = p.S529F on NM_152330.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.635); catalogued as COSV61089369; called by muse, mutect2, varscan2
- FRMPD1 | c.3548G>A p.G1183E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV66701132; called by muse, mutect2, varscan2
- FSHR | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.072); catalogued as COSV58621462; called by muse, mutect2, varscan2
- FSIP2 | c.16561G>A p.D5521N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs749016424, COSV58091458; called by muse, mutect2, varscan2
- FSTL5 | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.236); catalogued as COSV60207655; called by muse, mutect2, varscan2
- FZR1 | c.1124dup p.G376Rfs*4 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs1350973455; called by mutect2, pindel, varscan2
- GABBR2 | c.2415G>A p.L805= | Splice Region (SNP) | VAF 46/112 reads (41%) | catalogued as COSV52310583; called by muse, mutect2, varscan2
- GABRA2 | c.1282T>A p.L428M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV62916558; called by muse, mutect2, varscan2
- GALNT17 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs774180231, COSV61149361, COSV61166524; called by muse, mutect2, varscan2
- GCN1 | c.7108G>A p.A2370T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56110496; called by muse, mutect2, varscan2
- GIMAP1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV56188929; called by muse, mutect2, varscan2
- GJA5 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); catalogued as COSV54785101; called by muse, mutect2, varscan2
- GNA14 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100502413; called by muse, mutect2, varscan2
- GNB2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV51944052; called by muse, mutect2, varscan2
- GPR141 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as COSV100550195, COSV100550303, COSV57733031; called by muse, mutect2, varscan2
- GPRIN2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564932850, COSV65401563; called by muse, mutect2, varscan2
- GRM8 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772324014, COSV58803533; called by muse, mutect2, varscan2
- GSDME | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); catalogued as COSV61651026, COSV61652282; called by muse, mutect2, varscan2
- HACL1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58255250; called by muse, mutect2, varscan2
- HIVEP1 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as rs759783535, COSV65103125; called by muse, mutect2, varscan2
- HMGCLL1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51440507; called by muse, mutect2, varscan2
- HNF4G | c.739G>A p.D247N (on ENST00000354370 / NM_001330561.2; = p.D294N on NM_004133.5) | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as COSV62965356; called by muse, mutect2, varscan2
- HTATSF1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV54479798; called by muse, mutect2, varscan2
- ICA1 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV55581011; called by muse, mutect2, varscan2
- IGDCC3 | c.1853G>A p.R618K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV60078516; called by muse, mutect2, varscan2
- IGHV3-74 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.375); catalogued as rs771675236; called by muse, mutect2, varscan2
- IGSF1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as COSV63838529; called by muse, mutect2, varscan2
- IL18RAP | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1322791225, COSV51827277; called by muse, mutect2, varscan2
- IL18RAP | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51827287; called by muse, mutect2, varscan2
- IL1B | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV54522204; called by muse, mutect2, varscan2
- IL2RB | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777062765, COSV53426593; called by muse, mutect2, varscan2
- IL5RA | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs765215281, COSV56520683; called by muse, mutect2, varscan2
- IRGC | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV54985034; called by muse, mutect2, varscan2
- ITGA1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); catalogued as rs1471357591, COSV50886876; called by muse, mutect2, varscan2
- ITGA7 | c.3085C>A p.L1029M (on ENST00000555728; = p.L985M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV57697377; called by muse, mutect2, varscan2
- JCAD | c.566G>A p.W189* | Nonsense Mutation (SNP) | VAF 52/156 reads (33%) | catalogued as COSV64760557; called by muse, mutect2, varscan2
- KALRN | c.7525C>T p.Q2509* (on ENST00000360013 / NM_001024660.4; = p.Q812* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/36 reads (78%) | catalogued as COSV52259893; called by muse, mutect2, varscan2
- KCNA5 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239077980, COSV52908237; called by muse, mutect2, varscan2
- KCNH7 | c.1919A>G p.E640G | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100035411; called by muse, mutect2, varscan2
- KCNQ5 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372957711; called by muse, mutect2, varscan2
- KIAA0319 | c.407A>T p.D136V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV65499932; called by muse, mutect2
- KIAA1217 | c.5681C>T p.S1894F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV56819213; called by muse, mutect2, varscan2
- KIAA1522 | c.1543C>A p.P515T (on ENST00000373480 / NM_001198972.2; = p.P574T on NM_020888.3) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.872); catalogued as COSV53863859, COSV53865839; called by muse, mutect2, varscan2
- KIDINS220 | c.983C>A p.T328N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56755652; called by muse, mutect2, varscan2
- KIR2DL1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as rs746748835, COSV52412106; called by muse, varscan2
- KIR3DL3 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs752780817, COSV52547313; called by mutect2, varscan2
- KRT13 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV55840520; called by muse, mutect2, varscan2
- KRT39 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295417423, COSV62916972; called by muse, mutect2
- KRTAP11-1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60093929; called by muse, mutect2, varscan2
- KRTAP12-1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV59954959; called by muse, mutect2, varscan2
- KRTAP6-1 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 42/132 reads (32%) | PolyPhen benign (0.009); catalogued as COSV100228814, COSV58168585; called by muse, mutect2, varscan2
- LAMA2 | c.5189G>A p.R1730K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1211697213, COSV70351209; called by muse, mutect2, varscan2
- LAMB3 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 67/111 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV61917961; called by muse, mutect2, varscan2
- LAMC3 | c.2341C>T p.Q781* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV63093289; called by muse, mutect2, varscan2
- LAMC3 | c.4172C>T p.S1391F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV62653435; called by muse, mutect2, varscan2
- LIMCH1 | c.3100T>A p.Y1034N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV58288790; called by muse, mutect2, varscan2
- LINGO2 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV58056391, COSV58061271; called by muse, mutect2, varscan2
- LIPK | c.279G>A p.W93* | Nonsense Mutation (SNP) | VAF 12/13 reads (92%) | catalogued as COSV68201356; called by muse, mutect2
- LIX1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV57207454; called by muse, mutect2, varscan2
- LRG1 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 37/69 reads (54%) | catalogued as COSV56703423, COSV56704802; called by muse, mutect2, varscan2
- MAP3K10 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1212691976, COSV99454266; called by muse, mutect2, varscan2
- MAP3K10 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99454268; called by muse, mutect2, varscan2
- MAP3K9 | c.2750C>T p.S917F (on ENST00000554752 / NM_001284230.1; = p.S931F on NM_033141.4) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1419510662, COSV67122010; called by muse, mutect2, varscan2
- MARCO | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV59055920; called by muse, mutect2, varscan2
- MCTP2 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100752071; called by muse, mutect2, varscan2
- MEGF8 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV52091928; called by muse, mutect2, varscan2
- MFSD6 | c.1794G>A p.G598= | Splice Region (SNP) | VAF 8/18 reads (44%) | catalogued as rs1460195558, COSV55623730; called by muse, mutect2, varscan2
- MICAL2 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56322407; called by muse, mutect2, varscan2
- MME | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV64708669; called by muse, mutect2, varscan2
- MMRN2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs758783725, COSV62318286; called by muse, mutect2, varscan2
- MORC1 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as rs1456634655, COSV51720127; called by muse, mutect2, varscan2
- MOXD1 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV60941686, COSV60945833; called by muse, mutect2, varscan2
- MUC16 | c.30821C>T p.S10274F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.076); catalogued as COSV67457826; called by muse, mutect2, varscan2
- MUC16 | c.18401C>T p.S6134L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV67447839; called by muse, mutect2, varscan2
- MYH8 | c.4467T>G p.N1489K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs757966246, COSV67968103; called by muse, mutect2, varscan2
- MYO5C | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55908860; called by muse, mutect2, varscan2
- N6AMT1 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV58135050; called by muse, mutect2, varscan2
- NCOA7 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57657175; called by muse, mutect2, varscan2
- NCOR1 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1394706804, COSV51983235; called by muse, mutect2, varscan2
- NDEL1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55328673; called by muse, mutect2, varscan2
- NDNF | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1284840141, COSV65634072; called by muse, mutect2, varscan2
- NECTIN4 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV63513260; called by muse, mutect2, varscan2
- NIPAL1 | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV55007047; called by muse, mutect2, varscan2
- NOS1 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV57616002; called by muse, mutect2, varscan2
- NOTCH4 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs1429133208, COSV66682036; called by muse, mutect2, varscan2
- NR2E3 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58907848; called by muse, mutect2
- NRG3 | c.2101G>A p.E701K (on ENST00000404547 / NM_001370084.1; = p.E677K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV64571276; called by muse, mutect2, varscan2
- NSUN6 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs867410434, COSV66031726; called by muse, mutect2, varscan2
- NXPH3 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770843021, COSV60872064; called by muse, mutect2, varscan2
- NXPH3 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214834027, COSV100165504; called by muse, mutect2, varscan2
- OBI1 | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56146239; called by muse, mutect2, varscan2
- OLFML2A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV99992537; called by muse, mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by muse, mutect2, varscan2
- OR2D2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV55057539; called by muse, mutect2, varscan2
- OR2G3 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs267598476, COSV60682352, COSV60683036; called by muse, mutect2, varscan2
- OR2M5 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV63546077; called by muse, mutect2, varscan2
- OR2T2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778502785, COSV100737644; called by muse, mutect2, varscan2
- OR4A15 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV59036154; called by muse, mutect2, varscan2
- OR4A15 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59033435, COSV59036307; called by muse, mutect2, varscan2
- OR4S2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs267602971, COSV56746047; called by muse, mutect2, varscan2
- OR52R1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs866371519, COSV61888830; called by muse, mutect2, varscan2
- OR5L1 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61732697, COSV61733111, COSV61733957; called by muse, varscan2
- OR5P2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs779290699, COSV61490301; called by muse, mutect2, varscan2
- OR5R1 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100393535, COSV56572877; called by muse, mutect2, varscan2
- OR5T1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 115/192 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV57302139, COSV57303586; called by muse, mutect2, varscan2
- OR6C75 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV58552005; called by muse, mutect2, varscan2
- OR6S1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs765685226, COSV57838634; called by muse, mutect2, varscan2
- OR8D4 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58430874; called by muse, mutect2, varscan2
- OR8H2 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV57943751, COSV57945502; called by muse, mutect2, varscan2
- PACS1 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57698452; called by muse, mutect2, varscan2
- PAK5 | c.1775A>C p.Q592P | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62031687; called by muse, mutect2, varscan2
- PAMR1 | c.1970C>T p.P657L (on ENST00000619888 / NM_001001991.3; = p.P674L on NM_015430.4) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.192); catalogued as COSV53514018, COSV53517119; called by muse, mutect2, varscan2
- PASD1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV64856142; called by muse, mutect2
- PASD1 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64854553, COSV64856164; called by muse, mutect2, varscan2
- PATJ | c.3694G>A p.D1232N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV56251598; called by muse, mutect2, varscan2
- PAX7 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV64751195; called by muse, mutect2, varscan2
- PCARE | c.2828A>G p.Q943R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV59055823; called by muse, mutect2, varscan2
- PCDH17 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV64976128; called by muse, mutect2, varscan2
- PCDHA4 | c.544A>G p.K182E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV63543377; called by muse, mutect2, varscan2
- PCDHB6 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs868915597, COSV50705762; called by muse, mutect2, varscan2
- PCDHGA8 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV53932567; called by muse, mutect2, varscan2
- PCDHGB6 | c.507T>A p.D169E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV53980413; called by muse, mutect2, varscan2
- PCSK5 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV70447505; called by muse, mutect2, varscan2
- PDE5A | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs1336632327, COSV53350071, COSV99308704; called by muse, mutect2, varscan2
- PDGFRB | c.2989G>A p.G997S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV53838265; called by muse, mutect2, varscan2
- PDS5A | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.015); catalogued as COSV57827939; called by muse, mutect2, varscan2
- PDZD9 | c.742G>A p.D248N (on ENST00000424898 / NM_001363519.1; = p.D188N on NM_173806.4) | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV51672951; called by muse, mutect2, varscan2
- PEG3 | c.3676C>T p.R1226* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as rs867143279, COSV55638988; called by muse, mutect2, varscan2
- PHF12 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.474); catalogued as rs771016383, COSV52020506; called by muse, mutect2, varscan2
- PHF8 | c.914T>C p.I305T (on ENST00000357988 / NM_001184896.1; = p.I269T on NM_015107.3) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57684075; called by muse, mutect2, varscan2
- PI16 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1471984536, COSV101028665; called by muse, mutect2, varscan2
- PLCB4 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs267606066, COSV53795991; called by muse, mutect2, varscan2
- PLCG2 | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63871751; called by muse, mutect2, varscan2
- PLEKHG5 | c.139G>A p.D47N (on ENST00000400915 / NM_001042663.3; = p.D10N on NM_020631.6) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs750665205, COSV61703145, COSV61703694; called by muse, mutect2, varscan2
- POF1B | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53132952, COSV53136667; called by muse, mutect2, varscan2
- POLRMT | c.3359C>A p.P1120Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52116184, COSV99241669; called by muse, mutect2, varscan2
- POLRMT | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99241671; called by muse, mutect2, varscan2
- POTEE | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs370006093; called by muse, varscan2
- PRAME | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as rs751758532, COSV67161963; called by muse, mutect2, varscan2
- PRB2 | c.494A>C p.Q165P | Missense Mutation (SNP) | VAF 134/774 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV66983643; called by muse, varscan2
- PRDM1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV64845774, COSV64846463; called by muse, mutect2, varscan2
- PRDM15 | c.2244C>G p.D748E | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54155517; called by muse, mutect2, varscan2
- PRLR | c.657T>A p.S219R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51497517; called by muse, mutect2, varscan2
- PROKR2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1042038054, COSV54085035; called by muse, mutect2, varscan2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS35 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474009747, COSV63800824; called by muse, mutect2, varscan2
- PSG5 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV61654048; called by muse, mutect2, varscan2
- PSKH2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52610800, COSV52611333; called by muse, mutect2, varscan2
- PTGS2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100821729; called by muse, mutect2, varscan2
- PTK7 | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57847514; called by muse, mutect2, varscan2
- PTPN6 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs782130684, COSV59685172; called by muse, mutect2, varscan2
- PTPRD | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61960560; called by muse, mutect2, varscan2
- R3HCC1L | c.2120C>T p.P707L (on ENST00000612478 / NM_001256619.2; = p.P693L on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54402990; called by muse, mutect2, varscan2
- RAB3GAP1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51484679; called by muse, mutect2, varscan2
- RAD54B | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1442119215, COSV60252809; called by muse, mutect2, varscan2
- RALGAPB | c.3707C>T p.S1236F | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs747715098, COSV53434801; called by muse, mutect2, varscan2
- RELN | c.7343A>T p.Y2448F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as COSV59015125; called by muse, mutect2, varscan2
- RFPL4B | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV71437528; called by muse, mutect2, varscan2
- RIMS2 | c.2317C>T p.P773S (on ENST00000666250 / NM_001348490.2; = p.P581S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99167079; called by muse, mutect2
- RIMS2 | c.4202G>A p.G1401E (on ENST00000666250 / NM_001348490.2; = p.G972E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/145 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867105084, COSV51666954; called by muse, mutect2, varscan2
- RP1 | c.4846G>A p.E1616K | Missense Mutation (SNP) | VAF 79/112 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs868089931, COSV55115574; called by muse, mutect2, varscan2
- RPGRIP1 | c.3194C>T p.S1065F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV52852306; called by muse, mutect2, varscan2
- RPRM | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.024); catalogued as rs1407162784, COSV57988929; called by muse, mutect2, varscan2
- SACS | c.6088C>T p.P2030S | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV66543120; called by muse, mutect2, varscan2
- SCEL | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV62993964; called by muse, mutect2, varscan2
- SCN2A | c.5805C>G p.D1935E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV51847281; called by muse, mutect2, varscan2
- SCN8A | c.5216C>T p.P1739L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61985713; called by muse, mutect2, varscan2
- SEMA4C | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.065); catalogued as COSV59691478; called by muse, mutect2, varscan2
- SERPINB2 | c.883A>C p.T295P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV55093367; called by muse, mutect2, varscan2
- SH2D3C | c.2140G>A p.G714S (on ENST00000314830 / NM_170600.3; = p.G557S on NM_005489.4) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1181884159, COSV59126016; called by muse, mutect2, varscan2
- SH3YL1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62156901; called by muse, mutect2, varscan2
- SHOC1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59503954; called by muse, mutect2, varscan2
- SLC12A3 | c.2764G>A p.D922N (on ENST00000563236 / NM_001126108.2; = p.D931N on NM_000339.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs551520548, COSV52636530; called by muse, mutect2, varscan2
- SLC16A9 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68098318; called by muse, mutect2
- SLC25A36 | c.887C>T p.A296V (on ENST00000324194 / NM_001104647.3; = p.A295V on NM_018155.3) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV60782418; called by muse, mutect2, varscan2
- SLC26A8 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV62886553; called by muse, mutect2, varscan2
- SLC27A3 | c.2302C>T p.R768W (on ENST00000271857; = p.R640W on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs749428513, COSV55164521; called by muse, mutect2, varscan2
- SLC41A2 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV51607483; called by muse, mutect2, varscan2
- SLC52A3 | c.769A>T p.N257Y | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV54078138; called by muse, mutect2, varscan2
- SLC9A1 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV56054730; called by muse, mutect2, varscan2
- SLCO1C1 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs921146357, COSV56875402; called by muse, mutect2, varscan2
- SLCO4C1 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as rs867732414, COSV60517533, COSV60519352; called by muse, mutect2, varscan2
- SLITRK1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101000010, COSV65674775; called by muse, mutect2, varscan2
- SLITRK6 | c.353A>C p.H118P | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68390691; called by muse, mutect2, varscan2
- SMCO3 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV53763615, COSV53764981; called by muse, mutect2
- SP140 | c.2476A>C p.I826L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV100613664; called by mutect2, varscan2
- SP140L | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54745715; called by muse, mutect2, varscan2
- SPOCK1 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs750296583, COSV56455230, COSV99969023; called by muse, mutect2, varscan2
- ST18 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 81/113 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150692183; called by muse, mutect2, varscan2
- STEAP1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV51882195; called by muse, mutect2, varscan2
- STRA6 | c.1879G>A p.G627R | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.086); catalogued as COSV51434326; called by muse, mutect2, varscan2
- SULT1C4 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as rs1383802633, COSV55597431; called by muse, mutect2, varscan2
- SULT1E1 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV56947694; called by muse, mutect2, varscan2
- SV2C | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59223813; called by muse, mutect2, varscan2
- SYNDIG1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65232741; called by muse, mutect2, varscan2
- SYNE1 | c.22222C>T p.P7408S (on ENST00000367255 / NM_182961.4; = p.P7337S on NM_033071.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55027144; called by muse, mutect2, varscan2
- SYNPO2L | c.1144G>A p.E382K (on ENST00000394810 / NM_001114133.3; = p.E158K on NM_024875.5) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV65737972; called by muse, mutect2, varscan2
- SYT14 | c.719T>G p.M240R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as COSV55058072; called by muse, mutect2, varscan2
- SYT4 | c.1060T>C p.F354L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54901871; called by muse, mutect2, varscan2
- TAS2R16 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as COSV50796899; called by muse, mutect2, varscan2
- TBC1D5 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV53762668, COSV53771573; called by muse, mutect2, varscan2
- TBL3 | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.321); catalogued as COSV60342170, COSV60343236; called by muse, mutect2, varscan2
- TCHHL1 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV64286196; called by muse, mutect2, varscan2
- TDRD1 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV52590909; called by muse, mutect2, varscan2
- THBS2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1317152018, COSV100827847; called by muse, mutect2, varscan2
- THEMIS | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV64072264; called by muse, mutect2, varscan2
- TLN2 | c.4556C>T p.A1519V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV60891820; called by muse, mutect2, varscan2
- TLR1 | c.2099A>G p.N700S | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV58304907; called by muse, mutect2, varscan2
- TMEM132B | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs960028543, COSV54759187; called by muse, mutect2, varscan2
- TMEM132D | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV101396751, COSV70612388, COSV70614382; called by muse, mutect2, varscan2
- TNFRSF21 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57283421; called by muse, mutect2, varscan2
- TNNI3K | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs138299635; called by muse, mutect2, varscan2
- TRAF3IP3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs1357609595, COSV50555199; called by muse, mutect2, varscan2
- TRANK1 | c.7800G>A p.M2600I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1264579412, COSV57155634; called by muse, mutect2, varscan2
- TRIP11 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV50935116; called by muse, mutect2, varscan2
- TSHZ2 | c.2842C>T p.H948Y | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61589786; called by muse, mutect2, varscan2
- TTN | c.15874G>A p.E5292K (on ENST00000591111; = p.E4365K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | PolyPhen benign (0.374); catalogued as rs374682077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB4B | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); catalogued as COSV61117621; called by muse, mutect2, varscan2
- UBXN10 | c.753T>A p.F251L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV66772350; called by muse, mutect2, varscan2
- USH2A | c.9034C>T p.H3012Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56394868; called by muse, mutect2, varscan2
- VAV1 | c.2446G>A p.G816R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745431526, COSV100409074, COSV58379493, COSV58386932; called by muse, mutect2, varscan2
- WDR1 | c.965C>T p.S322L (on ENST00000382452; = p.S182L on NM_005112.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs1421462938, COSV66725183; called by muse, mutect2, varscan2
- XIRP2 | c.4920C>A p.N1640K (on ENST00000628543; = p.N1815K on NM_152381.6) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV54713660; called by muse, mutect2, varscan2
- XIRP2 | c.6419C>T p.P2140L (on ENST00000628543; = p.P2315L on NM_152381.6) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54713672; called by muse, mutect2, varscan2
- XIRP2 | c.7589C>T p.S2530F (on ENST00000628543; = p.S2705F on NM_152381.6) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54713688; called by muse, mutect2, varscan2
- XYLT2 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99190859; called by muse, mutect2, varscan2
- XYLT2 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99190860; called by muse, mutect2, varscan2
- ZBTB12 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1163402311, COSV64993983; called by muse, mutect2, varscan2
- ZDBF2 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV65622169, COSV65625388; called by muse, mutect2, varscan2
- ZEB1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV58048522; called by muse, mutect2, varscan2
- ZFAT | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs773288481, COSV64741548; called by muse, mutect2, varscan2
- ZFHX4 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV51463754; called by muse, mutect2, varscan2
- ZFHX4 | c.7069G>T p.D2357Y | Missense Mutation (SNP) | VAF 174/266 reads (65%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV51463846, COSV51502150; called by muse, mutect2
- ZFHX4 | c.7071T>A p.D2357E | Missense Mutation (SNP) | VAF 168/256 reads (66%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.986); catalogued as COSV51463933; called by muse, mutect2
- ZFPM2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs374581095, COSV65873087; called by muse, mutect2, varscan2
- ZMYND15 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.914); catalogued as COSV52643140; called by muse, mutect2, varscan2
- ZNF23 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | catalogued as COSV61841257; called by muse, mutect2, varscan2
- ZNF266 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs760017788, COSV63222519; called by muse, mutect2, varscan2
- ZNF326 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV61035769; called by muse, mutect2, varscan2
- ZNF462 | c.3316C>T p.P1106S | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as COSV52944531; called by muse, mutect2, varscan2
- ZNF483 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs760490223, COSV58515331; called by muse, mutect2, varscan2
- ZNF81 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV58577081; called by muse, mutect2, varscan2
- ZSCAN30 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54351322; called by muse, mutect2, varscan2
- FOXD4L5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); called by mutect2, varscan2
- FRG2C | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2
- IGHV2-5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR2DL4 | c.772G>A p.G258R (on ENST00000396284; = p.G219R on NM_001080770.2) | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIR3DL2 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NOVA1 | c.1154dup p.L385Ffs*3 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- PLEKHG5 | c.2276_2277insAGAGGA p.E759_E760dup (on ENST00000400915 / NM_001042663.3; = p.E722_E723dup on NM_020631.6) | In Frame Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- ABRA | c.111G>A p.A37= | Silent (SNP) | VAF 132/194 reads (68%) | catalogued as rs374350682, COSV61733015; called by muse, mutect2, varscan2
- ACACB | c.6801C>T p.L2267= | Silent (SNP) | VAF 60/179 reads (34%) | catalogued as COSV58139116; called by muse, mutect2, varscan2
- ACTL9 | c.237G>A p.L79= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV61006460; called by muse, mutect2, varscan2
- AGAP1 | c.2307C>T p.G769= (on ENST00000304032 / NM_001037131.3; = p.G716= on NM_014914.5) | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs1178579969, COSV58331803; called by muse, mutect2, varscan2
- AGTR2 | c.678C>T p.F226= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV64156486, COSV64156675; called by muse, mutect2, varscan2
- AMER3 | c.1101C>T p.I367= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs775061865, COSV58465826, COSV58466384; called by muse, mutect2, varscan2
- ANKEF1 | c.1281G>A p.G427= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV65692044; called by muse, mutect2, varscan2
- AP3B2 | c.1677G>A p.L559= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV55611340; called by muse, mutect2, varscan2
- APOB | c.7369C>T p.L2457= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV51942374; called by muse, mutect2, varscan2
- ASNS | c.789C>T p.S263= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV51553657; called by muse, mutect2, varscan2
- ASXL3 | c.3531G>A p.E1177= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV52471476; called by muse, mutect2, varscan2
- ATP8A2 | c.2715G>A p.Q905= | Silent (SNP) | VAF 70/148 reads (47%) | catalogued as COSV54951328; called by muse, mutect2, varscan2
- ATXN1 | c.969C>T p.V323= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs757064338, COSV55221755; called by muse, mutect2, varscan2
- AVPR1B | c.873C>T p.I291= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs149631562, COSV65638093; called by muse, mutect2, varscan2
- AXDND1 | c.978C>T p.F326= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV62644797; called by muse, mutect2, varscan2
- BAP1 | c.186C>T p.V62= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs199608453, COSV56237074, COSV99964684; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BPTF | c.5562A>G p.L1854= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as rs1264156858, COSV58837593, COSV58840953; called by muse, mutect2, varscan2
- BSN | c.2784C>T p.L928= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV56522062; called by muse, mutect2, varscan2
- CACNA1H | c.4401C>T p.I1467= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs373686500; called by muse, mutect2, varscan2
- CAMK1 | c.1005G>A p.G335= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV56539433; called by muse, mutect2, varscan2
- CD22 | c.1548T>A p.L516= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV50057833; called by muse, mutect2, varscan2
- CD248 | c.1383T>A p.P461= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV60937051; called by muse, mutect2
- CFAP70 | c.111C>T p.F37= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV60284800; called by muse, mutect2, varscan2
- CHRNA9 | c.738C>T p.I246= | Silent (SNP) | VAF 142/405 reads (35%) | catalogued as COSV59575030; called by muse, mutect2, varscan2
- CLCN2 | c.1269C>T p.A423= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV55602446; called by muse, mutect2, varscan2
- COL6A5 | c.6555G>A p.E2185= (on ENST00000312481; = p.E2181= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs563800918, COSV55207906; called by muse, mutect2, varscan2
- CPXM1 | c.2094C>T p.F698= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs766761505, COSV66044544; called by muse, mutect2, varscan2
- CSMD2 | c.3181T>C p.L1061= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs1452783410, COSV53921725; called by muse, mutect2, varscan2
- CYP4F22 | c.103C>T p.L35= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs915376136, COSV54109811; called by muse, mutect2, varscan2
- DAG1 | c.363C>T p.P121= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV58185442; called by muse, mutect2, varscan2
- DCDC1 | c.57C>T p.S19= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1400816585, COSV60848618; called by muse, mutect2, varscan2
- DISP3 | c.1426C>T p.L476= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV53831216; called by muse, mutect2, varscan2
- DNAH2 | c.11037C>T p.F3679= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs768204339, COSV66722039; called by muse, mutect2, varscan2
- DNAH3 | c.4635C>T p.L1545= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV54533098, COSV54547947; called by muse, mutect2, varscan2
- DNAH5 | c.762G>A p.E254= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs775558528, COSV54237131; called by muse, mutect2, varscan2
- DNAH8 | c.1299C>T p.I433= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs372590465; called by muse, mutect2, varscan2
- DUOX2 | c.2484C>T p.F828= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV66530954; called by muse, mutect2, varscan2
- EFCAB6 | c.4335C>T p.S1445= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV53066777; called by muse, mutect2, varscan2
- FAM83B | c.1323C>T p.A441= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100174332; called by muse, mutect2, varscan2
- FAT4 | c.8745C>T p.S2915= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV58694562; called by muse, mutect2, varscan2
- FBXO30 | c.420C>T p.T140= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV52791661; called by muse, mutect2, varscan2
- FCER1A | c.21C>T p.S7= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as rs1331987787, COSV63667742; called by muse, mutect2, varscan2
- FMN2 | c.3696C>T p.I1232= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV60427747, COSV60438650; called by muse, mutect2, varscan2
- FPR3 | c.382C>T p.L128= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV59329967, COSV59332218; called by muse, mutect2, varscan2
- FYB1 | c.75G>A p.G25= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV60950467; called by muse, mutect2, varscan2
- GAD2 | c.396G>A p.V132= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV52162019; called by muse, mutect2, varscan2
- GALNT13 | c.786G>A p.L262= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV67227808; called by muse, mutect2, varscan2
- GCAT | c.714C>T p.F238= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV50648769; called by muse, mutect2
- GGT5 | c.1311G>A p.R437= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs772642258, COSV54071130; called by muse, mutect2, varscan2
- GIMAP4 | c.747G>A p.E249= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs770039406, COSV55433529, COSV55434673, COSV99750290; called by muse, mutect2, varscan2
- GIMAP5 | c.396G>A p.R132= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV57530151; called by muse, mutect2, varscan2
- GJA8 | c.900C>T p.F300= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as rs782293999, COSV53789063; called by muse, mutect2, varscan2
- IGHA1 | c.357T>C p.S119= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, varscan2
- IL16 | c.2445C>T p.S815= (on ENST00000302987 / NM_172217.5; = p.S114= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1439209226, COSV100267426; called by muse, mutect2, varscan2
- IL2 | c.84G>A p.K28= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV56986394; called by muse, mutect2, varscan2
- INCENP | c.856C>T p.L286= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV53917731; called by muse, mutect2, varscan2
- INPPL1 | c.2557C>T p.L853= | Silent (SNP) | VAF 97/174 reads (56%) | catalogued as COSV53357145; called by muse, mutect2, varscan2
- ITGA11 | c.1050C>T p.F350= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV59874552; called by muse, mutect2, varscan2
- ITGAD | c.828G>A p.E276= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV66758734; called by muse, mutect2, varscan2
- ITGB3 | c.175C>T p.L59= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV71384497; called by muse, mutect2, varscan2
- KCND2 | c.84G>A p.P28= | Silent (SNP) | VAF 75/174 reads (43%) | catalogued as rs773004768, COSV58571387; called by muse, mutect2, varscan2
- KCNH7 | c.1920G>A p.E640= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV100035409; called by muse, mutect2, varscan2
- KCNJ1 | c.291C>T p.L97= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV60662191; called by muse, mutect2, varscan2
- KCNS2 | c.823C>T p.L275= | Silent (SNP) | VAF 136/183 reads (74%) | catalogued as COSV54639499; called by muse, mutect2, varscan2
- KIAA0319 | c.405G>A p.E135= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV65499938; called by muse, mutect2
- KIF4B | c.2316G>A p.K772= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV70530254; called by muse, mutect2, varscan2
- LIF | c.579G>A p.Q193= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs765035600, COSV50776850; called by muse, mutect2, varscan2
- LIFR | c.1932C>T p.L644= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs758012108, COSV54693762; called by muse, mutect2, varscan2
- LILRA1 | c.1413C>T p.V471= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52182357; called by muse, mutect2, varscan2
- LMAN2 | c.495C>T p.P165= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57425087; called by muse, mutect2, varscan2
- LOXL1 | c.1644C>T p.F548= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV56095078; called by muse, mutect2, varscan2
- LRP4 | c.5427C>T p.I1809= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs763024440, COSV66136938; called by muse, mutect2, varscan2
- LRRC4C | c.636C>T p.I212= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV53430874; called by muse, mutect2, varscan2
- LY9 | c.345C>T p.S115= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as COSV54435548; called by muse, mutect2, varscan2
- MAP3K2 | c.1587C>T p.S529= | Silent (SNP) | VAF 87/210 reads (41%) | catalogued as rs1558972133, COSV61295148; called by muse, mutect2, varscan2
- MARCO | c.12G>A p.K4= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV59052913, COSV59055910; called by muse, mutect2, varscan2
- MARK4 | c.402G>A p.V134= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs756275545, COSV53465720; called by muse, mutect2, varscan2
- MCTP2 | c.2382C>T p.P794= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100752072; called by muse, mutect2, varscan2
- MEI1 | c.2506T>C p.L836= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as COSV55904660; called by muse, mutect2, varscan2
- METTL6 | c.409C>T p.L137= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV67542337; called by muse, mutect2, varscan2
- MMP3 | c.1191G>A p.K397= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as COSV55405685, COSV55406909; called by muse, mutect2, varscan2
- MRGPRX1 | c.810C>T p.I270= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV57108147; called by muse, mutect2, varscan2
- MTUS2 | c.1944C>T p.I648= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV70918053; called by muse, mutect2, varscan2
- MUC16 | c.26661C>T p.F8887= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs76894959, COSV67477722; called by muse, mutect2, varscan2
- MXRA5 | c.2370C>T p.V790= | Silent (SNP) | VAF 32/43 reads (74%) | catalogued as COSV54241267; called by muse, mutect2, varscan2
- NDFIP2 | c.867C>T p.F289= | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as COSV54528977; called by muse, mutect2, varscan2
- NEK9 | c.516C>T p.I172= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV53132072; called by muse, mutect2, varscan2
- NKG7 | c.375C>T p.I125= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV52467750; called by muse, mutect2, varscan2
- NLGN4X | c.2061C>T p.F687= | Silent (SNP) | VAF 29/39 reads (74%) | catalogued as rs1169457820, COSV52007306; called by muse, mutect2, varscan2
- NOB1 | c.843C>T p.S281= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV52062278; called by muse, mutect2, varscan2
- NOSTRIN | c.189G>A p.T63= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs767729458, COSV58322434; called by muse, mutect2, varscan2
- NXPH2 | c.396G>A p.G132= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs773053542, COSV55644583; called by muse, mutect2, varscan2
- OLFML2A | c.948G>A p.L316= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1326014107, COSV99992535; called by muse, mutect2, varscan2
- OR10R2 | c.189C>T p.V63= | Silent (SNP) | VAF 63/124 reads (51%) | catalogued as COSV63769104; called by muse, mutect2, varscan2
- OR11H6 | c.459C>T p.I153= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs1222460608, COSV59644560; called by muse, mutect2, varscan2
- OR51I2 | c.156G>A p.E52= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV58299341; called by muse, mutect2, varscan2
- OR52E6 | c.501G>A p.R167= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV61432564; called by muse, mutect2, varscan2
- OR5B12 | c.180C>T p.F60= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV56904325; called by muse, mutect2, varscan2
- OR5B17 | c.33C>T p.I11= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV62160610; called by muse, mutect2, varscan2
- OR5L1 | c.753C>T p.F251= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs1381189325, COSV61734552, COSV61735291, COSV61735761; called by muse, varscan2
- OR6K3 | c.507C>T p.F169= (on ENST00000368146; = p.F153= on NM_001005327.2) | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV63745527; called by muse, mutect2, varscan2
- OR6K6 | c.246C>T p.A82= (on ENST00000368144; = p.A58= on NM_001005184.1) | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs779084115, COSV63744437; called by muse, mutect2, varscan2
- OTOA | c.417C>T p.I139= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV53758256; called by muse, mutect2, varscan2
- PADI2 | c.1074C>T p.I358= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs551094660, COSV64946074; called by muse, mutect2, varscan2
- PCDHA4 | c.1227G>A p.L409= | Silent (SNP) | VAF 80/217 reads (37%) | catalogued as rs782005854, COSV63543383; called by muse, mutect2, varscan2
- PCDHGA9 | c.2307C>T p.I769= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV53980403; called by muse, mutect2, varscan2
- PCLO | c.4516A>C p.R1506= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV61647334; called by muse, mutect2, varscan2
- PER2 | c.3681T>A p.I1227= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV54525414; called by muse, mutect2, varscan2
- PIGQ | c.669C>T p.V223= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV50316284; called by muse, mutect2, varscan2
- PLCL2 | c.2706C>T p.S902= (on ENST00000615277 / NM_001144382.2; = p.S776= on NM_015184.5) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV67623283; called by muse, mutect2, varscan2
- PLEKHG1 | c.2064G>A p.R688= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV62048829; called by muse, mutect2, varscan2
- POM121C | c.1695C>T p.S565= (on ENST00000607367; = p.S323= on NM_001099415.3) | Silent (SNP) | VAF 84/193 reads (44%) | catalogued as COSV57547329; called by muse, mutect2, varscan2
- PRAMEF18 | c.477C>T p.F159= | Silent (SNP) | VAF 78/402 reads (19%) | called by muse, mutect2, varscan2
- PRB4 | c.519C>T p.S173= | Silent (SNP) | VAF 118/299 reads (39%) | catalogued as rs773957600, COSV54396889, COSV99686468; called by muse, mutect2, varscan2
- PRDM2 | c.99C>T p.F33= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs143175897; called by muse, mutect2, varscan2
- PREX1 | c.816C>T p.L272= | Silent (SNP) | VAF 239/329 reads (73%) | catalogued as rs267605975, COSV64253545; called by muse, mutect2, varscan2
- PTGS2 | c.1527A>C p.V509= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV100821730; called by muse, mutect2, varscan2
- PTPRD | c.2256G>A p.V752= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV61960550; called by muse, mutect2, varscan2
- PTPRK | c.2301C>T p.L767= (on ENST00000368215 / NM_001291984.2; = p.L768= on NM_002844.4) | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV63902139; called by muse, mutect2, varscan2
- PXDN | c.2634C>T p.F878= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs750398617, COSV53226396; called by muse, mutect2, varscan2
- RAI1 | c.3498C>T p.G1166= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV55395237; called by muse, mutect2, varscan2
- RCBTB2 | c.1029C>T p.I343= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV60650695; called by muse, mutect2, varscan2
- RCSD1 | c.741G>A p.E247= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV63257718; called by muse, mutect2, varscan2
- RGL1 | c.2157C>T p.A719= (on ENST00000360851 / NM_001297672.2; = p.A754= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV58989010; called by muse, mutect2, varscan2
- RGPD2 | c.5184G>A p.T1728= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1334787144, COSV100552924; called by mutect2, varscan2
- RIBC2 | c.306C>T p.F102= | Silent (SNP) | VAF 42/65 reads (65%) | catalogued as COSV100663394, COSV61581869; called by muse, mutect2, varscan2
- RNPEP | c.1389C>T p.F463= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV55242285; called by muse, mutect2, varscan2
- RRP9 | c.1155C>T p.L385= | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as COSV51755379; called by muse, mutect2, varscan2
- SAMD12 | c.456C>T p.L152= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs1222439121, COSV59052664; called by muse, mutect2, varscan2
- SAMD9 | c.579G>A p.P193= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs142131920; called by muse, mutect2, varscan2
- SCN11A | c.4080C>T p.F1360= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs752386014, COSV56569644; called by muse, mutect2, varscan2
- SCN1A | c.3120G>A p.R1040= (on ENST00000303395 / NM_001202435.3; = p.R1029= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV57676758, COSV57685117; called by muse, mutect2, varscan2
- SCN9A | c.2061G>A p.Q687= (on ENST00000303354; = p.Q676= on NM_002977.3) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1245649359, COSV57615308; called by muse, mutect2, varscan2
- SERPINB4 | c.435G>A p.K145= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1174385232, COSV61985505; called by muse, mutect2, varscan2
- SHANK2 | c.3201G>A p.R1067= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV53606989; called by muse, mutect2, varscan2
- SLC22A25 | c.1056C>T p.F352= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV60597164; called by muse, mutect2, varscan2
- SLITRK5 | c.1359C>T p.F453= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs760927848, COSV61521289; called by muse, mutect2, varscan2
- SPAG6 | c.267T>A p.V89= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV57621758; called by muse, mutect2, varscan2
- SPAM1 | c.342C>T p.I114= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV56142317, COSV56148082; called by muse, mutect2, varscan2
- SPATA31A1 | c.1401C>T p.F467= | Silent (SNP) | VAF 102/419 reads (24%) | called by muse, mutect2, varscan2
- SPRR2B | c.90G>A p.P30= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs762728746, COSV100482202, COSV100482274; called by muse, varscan2
- SPTA1 | c.5730C>A p.T1910= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV63756167; called by muse, mutect2, varscan2
- SYNDIG1L | c.387G>A p.R129= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV59047928; called by muse, mutect2, varscan2
- SYNE1 | c.26352C>T p.F8784= (on ENST00000367255 / NM_182961.4; = p.F8736= on NM_033071.3) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV55027110; called by muse, mutect2, varscan2
- SYT2 | c.144G>A p.K48= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV66142423; called by muse, mutect2, varscan2
- TCERG1 | c.1107C>T p.P369= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV57037402; called by muse, mutect2, varscan2
- TFAP2B | c.1056C>T p.S352= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV53829164; called by muse, mutect2, varscan2
- TFPI | c.225C>T p.F75= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV51902672; called by muse, mutect2, varscan2
- TGFB1I1 | c.771T>C p.C257= (on ENST00000394863 / NM_001042454.3; = p.C240= on NM_015927.4) | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV62358583; called by muse, mutect2, varscan2
- TMEM200A | c.1470G>A p.R490= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV51655573; called by muse, varscan2
- TMPRSS11A | c.294G>A p.K98= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV58359522; called by muse, mutect2, varscan2
- TPPP | c.375G>A p.K125= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV62192775; called by muse, mutect2, varscan2
- TRAV16 | c.30G>A p.V10= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs369301878; called by muse, varscan2
- TRPV1 | c.624C>T p.I208= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs201566423, COSV51520837; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSHZ1 | c.1158G>A p.A386= (on ENST00000580243 / NM_001308210.2; = p.A341= on NM_005786.6) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1018481672, COSV59012759; called by muse, mutect2
- TTN | c.4659G>A p.Q1553= (on ENST00000591111; = p.Q1507= on NM_003319.4) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV60172436; called by muse, mutect2, varscan2
- USP43 | c.3282G>A p.G1094= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs369028702; called by muse, mutect2, varscan2
- WWC1 | c.2971C>T p.L991= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV54653962; called by muse, mutect2, varscan2
- XDH | c.2280G>A p.E760= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV65149841; called by muse, mutect2, varscan2
- ZBED8 | c.1446C>T p.I482= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as rs375415141; called by muse, mutect2, varscan2
- ZCCHC14 | c.2487C>T p.P829= (on ENST00000268616; = p.P966= on NM_015144.3) | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs768142509, COSV51887856; called by muse, mutect2, varscan2
- ZFHX4 | c.126G>A p.R42= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV51463698, COSV51473452; called by muse, mutect2, varscan2
- ZNF366 | c.2130G>A p.R710= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV59216974; called by muse, mutect2, varscan2
- ZNF526 | c.1797G>A p.R599= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV55899938; called by muse, mutect2, varscan2
- ATP8A2 | c.507+896C>T | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- FCHO1 | c.-1G>A | 5'UTR (SNP) | VAF 34/95 reads (36%) | catalogued as COSV99406047; called by muse, mutect2, varscan2
- KCNK1 | c.356-16647G>A | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as rs1199564564; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85434G>A | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs267600068, COSV72279811; called by muse, mutect2, varscan2
- MIR1323 | n.23G>A | RNA (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- MIR890 | n.54C>T | RNA (SNP) | VAF 33/38 reads (87%) | called by muse, mutect2, varscan2
- PDZRN4 | c.844-68447C>T | Intron (SNP) | VAF 34/86 reads (40%) | catalogued as rs1374169591, COSV100114236; called by muse, mutect2, varscan2
- PRR12 | c.52-193C>T | Intron (SNP) | VAF 11/29 reads (38%) | catalogued as COSV69818329; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23927C>T | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as COSV101042720; called by muse, mutect2, varscan2
